Somatic mutation profile of tumor specimen ALCH-B0CD-TTP1-A (aliquot ALCH-B0CD-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0CD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 85.8 years (31,331 days).
Specimen ALCH-B0CD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0ee2bec-1ef2-4a97-9e10-68af2cd8da58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0CD-NB1-A (Blood Derived Normal), aliquot ALCH-B0CD-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c88724e-e52e-4bd8-9bfe-516fe21d519d

The open-access MAF lists 37 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 8, Intron 4, Frame Shift Del 2, In Frame Del 1, RNA 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3028G>A p.D1010N | Missense Mutation (SNP) | VAF 59/114 reads (52%) | hotspot (GDC flag); SIFT tolerated (0.18); PolyPhen possibly damaging (0.853); catalogued as COSV59259218, COSV59259530, COSV59268643; called by muse, mutect2, varscan2
- MLH3 | c.563C>G p.S188C | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1318542248, COSV99464824; called by muse, mutect2
- OCA2 | c.1347C>A p.F449L | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.326); catalogued as COSV62348452, COSV62356490; called by muse, mutect2
- PABPC5 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs780058298, COSV57040246, COSV57043472; called by muse, mutect2, varscan2
- PES1 | c.1558G>T p.D520Y | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV58828080; called by mutect2, varscan2
- PLXNA4 | c.2953G>A p.V985M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761967324; called by muse, mutect2, varscan2
- RNF168 | c.197C>T p.T66I | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as rs147937658; called by muse, mutect2, varscan2
- ATP8A1 | c.3087G>T p.W1029C | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- C9orf57 | c.447_455del p.T150_H152del (on ENST00000377024 / NM_001371610.1; = p.T128_H130del on NM_001128618.2) | In Frame Del (DEL) | VAF 7/42 reads (17%) | called by mutect2, pindel, varscan2
- CDH13 | c.263C>A p.T88N | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.142); called by muse, mutect2
- COQ8A | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- ETV4 | c.1216G>A p.G406S | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- F8 | c.3431G>A p.S1144N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- HNRNPF | c.920A>G p.N307S | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.023); called by muse, mutect2
- KANSL3 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.395); called by muse, mutect2
- PRG4 | c.488del p.N163Ifs*38 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by pindel, varscan2
- SRPRA | c.921dup p.T308Yfs*4 | Frame Shift Ins (INS) | VAF 9/64 reads (14%) | called by mutect2, pindel, varscan2
- STAT5A | c.1681-1G>A p.X561_splice | Splice Site (SNP) | VAF 8/66 reads (12%) | called by muse, varscan2
- STAT5A | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.751); called by muse, varscan2
- STAT5A | c.2094G>C p.Q698H | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.711); called by muse, mutect2
- TAF1L | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM67 | c.178C>T p.L60F | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- WSCD1 | c.801A>G p.I267M | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- ZFAND1 | c.383_386del p.S128Nfs*17 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- FLT1 | c.1980A>G p.A660= | Silent (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- PLP1 | c.348G>A p.T116= | Silent (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- SF3A2 | c.525C>A p.P175= | Silent (SNP) | VAF 9/95 reads (9%) | called by muse, mutect2
- STAT5A | c.1605G>A p.Q535= | Silent (SNP) | VAF 14/143 reads (10%) | called by muse, varscan2
- STAT5A | c.1731G>A p.V577= | Silent (SNP) | VAF 14/130 reads (11%) | catalogued as rs145218627; called by muse, varscan2
- SYNM | c.3547C>T p.L1183= | Silent (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2
- TAF1L | c.1833A>G p.S611= | Silent (SNP) | VAF 8/56 reads (14%) | called by muse, varscan2
- TOR1AIP1 | c.999C>G p.V333= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- MBNL1 | c.-790+453C>T | Intron (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2, varscan2
- PSMD13 | c.209+41C>T | Intron (SNP) | VAF 8/118 reads (7%) | catalogued as rs1391803846; called by muse, mutect2
- SDAD1 | c.196-71T>G | Intron (SNP) | VAF 4/41 reads (10%) | called by muse, varscan2
- TOM1 | c.899+846A>G | Intron (SNP) | VAF 6/38 reads (16%) | called by muse, varscan2
- ZNF322P1 | n.383C>T | RNA (SNP) | VAF 8/60 reads (13%) | called by mutect2, varscan2
